Surgical pathology report (de-identified scan), TCGA case TCGA-DI-A2QY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MD Anderson, specimen TCGA-DI-A2QY-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time: '

DIAGNOSIS

(A) OMENTAL NODULE:

Fibrosis and inflammation, no tumor present.

(B) ILEAL NODULE:

Fibrosis, inflammation, and microcalcification.

No tumor present.

(C) UTERUS, CERVIX AND BILATERAL TUBES AND OVARIES, TOTAL HYSTERECTOMY AND SALPINGO-OOPHORECTOMY:

UTERUS: MIXED HIGH GRADE CARCINOMA, PREDOMINANTLY PAPILLARY SEROUS CARCINOMA OF THE ENDOMETRIUM, WITH FOCAL AREAS OF ENDOMETRIOID ENDOMETRIAL ADENOCARCINOMA, INVADING 11 MM OF THE 22 MM MYOMETRIUM.

Leiomyoma.

CERVIX: PAPILLARY SEROUS CARCINOMA INVOLVING THE CERVIX, INVADING 4.0 MM OF 10 MM CERVICAL STROMA (LEFT LATERAL).

ALL SURGICAL MARGINS ARE AT LEAST 5 MM AWAY FROM THE TUMOR.

Bilateral tubes and ovaries: No tumor present.

(D) RIGHT PARA-AORTIC AND COMMON ILIAC LYMPH NODE:

Three lymph nodes, no tumor present.

(E) RIGHT COMMON ILIAC LYMPH NODE:

Two lymph nodes, no tumor present.

(F) LEFT AORTIC LYMPH NODE:

Three lymph nodes, no tumor present.

(G) LEFT COMMON ILIAC LYMPH NODE:

Three lymph nodes, no tumor present.

(H) LEFT PELVIC LYMPH NODE:

One lymph node, no tumor present.

(I) LEFT OBTURATOR LYMPH NODE:

Three lymph nodes, no tumor present.

(J) LEFT PELVIC LYMPH NODE:

Five lymph nodes, no tumor present.

(K) RIGHT OBTURATOR LYMPH NODE:

One lymph node, no tumor present.

(L) OMENTAL BIOPSY #1:

Adipose tissue, no tumor present.

(M) OMENTAL BIOPSY #2:

Adipose tissue, no tumor present.

(N) BLADDER PERITONEUM:

Fibroconnective tissue, no tumor present.

(O) ANTERIOR ABDOMINAL WALL PERITONEUM:

Fibroconnective tissue, no tumor present.

(P) CUL-DE-SAC PERITONEUM:

Fibroconnective tissue with acute inflammation, no tumor present.

Reviewed/Initials	KMT/lu 9/3/11	

ICD-0-3
carcinoma, serous (8441/3) and
endometrioid adenocarcinoma (8381/3) -
Code to highest 8441/3
Site: endometrium C54.1
lu
9/3/11

Entire report and diagnosis completed by .

hD

[page 2 of 3]
GROSS DESCRIPTION

(A) OMENTAL NODULE - A roughly ovoid tan-yellow soft tissue 0.7 x 0.8 x 0.7 cm. The external surface is roughened by fibrous tags. The specimen is bisected and reveals a cyst containing yellow mucoid material. The specimen is submitted entirely in A for frozen section.

*FS/DX: FIBROSIS AND INFLAMMATION, NO TUMOR PRESENT.

(B) OMENTAL NODULE - Two grossly unremarkable fibroadipose tissue fragments measuring 1.0 x 0.4 x 0.4 cm each, entirely submitted in frozen B.

*FS/DX: FIBROSIS, INFLAMMATION, AND MICROCALCIFICATIONS; NO TUMOR PRESENT.

(C) UTERUS, CERVIX AND BILATERAL TUBES AND OVARY PLUS CUFF, TOTAL HYSTERECTOMY AND SALPINGO-OOPHORECTOMY - The uterus measures 9.0 x 5.0 x 5.0 cm and cervix measures 3.0 cm in length and 2.5 cm in diameter. A 1.5 x 1.0 cm mucosal ulceration is identified in squamocolumnar junction in left aspect of the ectocervix. The endocervical canal is unremarkable. The uterus is showed thickened endometrium that is pink-tan and polypoid. Sections reveals thickened endometrial tissue with pale tan and some polypoid appearance. The endometrium measures 0.3 to 0.5 cm in thickness. Multiple myometrial nodules are also identified with gross appearance of leiomyoma. The remaining endometrium was submitted in toto. The myometrium measures 1.6 cm from the level of fundus.

Left fallopian tube measures 5.0 cm in length with fimbriated end and measures 0.5 cm in diameter. The left ovary measures 2.5 x 1.0 x 1.0 cm. Grossly, the left ovary is grossly normal.

Right ovary measures 2.5 x 1.0 x 1.0 cm with 1.0 cm cyst containing clear fluid. Right fallopian tube measures 6.0 cm in length with fimbriated end.

SECTION CODE: C1, cervix, anterior, from normal area; C2-C4, left lateral cervix ulcer; C5-C11, full-thickness of endometrium, myometrium and serosal surface from anterior wall, submitted from fundus to lower uterine segment; C11 from lower uterine segment; C12, posterior cervix; C13-C18, posterior full-thickness from fundus to lower uterine segment; C19-C20, thickened endometrium with endocervical canal; C21-C22, multiple myometrial nodules; C23, left ovary and fallopian tube; C24, right ovarian and fallopian tube.

(D) RIGHT PARAAORTIC AND COMMON ILIAC LYMPH NODE, CLIP MARKS SUPERIOR NODE - One piece of fibroadipose tissue measuring 4.0 x 3.0 x 0.5 cm. Three potential lymph nodes are identified, submitted in D1-D2.

(E) RIGHT COMMON ILIAC LYMPH NODE - Multiple pieces of fibroadipose tissue measuring 1.5 x 1.5 x 0.3 cm in aggregate. No lymph nodes are identified. The entire specimen is submitted in cassette E1-E2.

(F) LEFT AORTIC LYMPH NODE, CLIP MARKS MOST OF SUPERIOR NODE - One piece of fibroadipose tissue measuring 5.0 x 2.0 x 1.0 cm. Three potential lymph nodes are identified and submitted in F1 to F2.

(G) LEFT COMMON ILIAC LYMPH NODE - A small piece of fibroadipose tissue with three potential lymph nodes identified. All the lymph nodes are submitted in cassette G.

(H) LEFT PELVIC LYMPH NODE - One piece of fibroadipose tissue measuring 3.0 x 2.0 x 0.6 cm. One potential lymph node is identified and the lymph node is bisected and submitted in toto in cassette H.

(I) LEFT OBTURATOR LYMPH NODE - A small piece of adipose tissue measuring 2.0 x 2.0 x 0.5 cm. Three potential lymph nodes are identified. They are submitted in toto in cassette I.

(J) LEFT PELVIC LYMPH NODE - One piece of fibroadipose tissue with multiple lymph nodes. The specimen measures 4.0 x 3.0 x 1.0 cm. All the lymph nodes are submitted.

SECTION CODE: J1, one bisected lymph node; J2, two potential lymph nodes; J3, two potential lymph nodes. SQ/elk

(K) RIGHT OBTURATOR LYMPH NODE - One piece of fibroadipose tissue measuring 4.0 x 4.0 x 0.5 cm. One large lymph node measuring 1.4 x 0.9 x 0.4 cm is identified. The staple is bisected and submitted in toto in cassette K.

(L) OMENTAL BIOPSY #1 - One piece of omentum measuring 10.0 x 7.0 x 0.8 cm. Sectioning of the omentum shows no gross abnormalities. Five representative sections are submitted in cassette L1-L5.

(M) OMENTUM BIOPSY #2 - One piece of omentum measuring 10.0 x 4.0 x 1.0 cm. No gross abnormalities are identified. Representative sections are submitted in cassettes M1-M5.

(N) BLADDER PERITONEUM - A small piece of fibroadipose tissue with esophageal lining. The specimen measures 1.2 x 0.3 x 0.3 cm. The entire specimen is submitted in cassette N.

(O) ANTERIOR ABDOMINAL WALL PERITONEUM - One piece of adipose tissue with mesothelial lining. The specimen measures 1.8 x 1.0 x 0.4 cm. No gross abnormalities are identified. The specimen is submitted in toto in cassette O.

(P) CUL-DE-SAC PERITONEUM - A small piece of adipose tissue measuring 0.3 x 0.3 x 0.1 cm. The specimen is submitted in

[page 3 of 3]
CLINICAL HISTORY

Endometrial cancer.

SNOMED CODES

Released by:

PhD

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 2e968754-16f2-4e6b-985f-dc3722958b4d (TCGA-DI-A2QY.C78D0C27-34C3-44C4-9814-94EEE8A8AB95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).